HCMI case HCM-SANG-0265-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/f8a9aab0-6017-483d-b053-9393c6a5af2d

Demographics
Sex at birth: female; Days to birth: -18,810 days (51.5 years before the index date).

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.9; Tissue or organ of origin: Colon, NOS; Classification of tumor: primary; Tumor grade: GX; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Uicc clinical stage: Stage IIIC; Uicc pathologic m: M1a; Uicc pathologic n: N0; Uicc pathologic stage: Stage IVA; Uicc pathologic t: T0; Uicc staging system edition: 7th.
   Recorded as not given: neoadjuvant treatment (type not reported).
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C78.7; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Liver; Classification of tumor: metastasis.
   Pathology details: Lymphatic invasion present: No; Perineural invasion present: No; Vascular invasion present: No.

Family history
- Relative with cancer history: no.

Biospecimens (7 samples)
- Sample HCM-SANG-0265-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample HCM-SANG-0265-C18-06A-01D-A80T-32: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
- Sample HCM-SANG-0265-C18-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-SANG-0265-C18-10A-01D-A80T-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample HCM-SANG-0265-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
- Samples HCM-SANG-0265-C18-85A-01D-A80T-32, HCM-SANG-0265-C18-85A-01R-A80W-32 (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid.
